CPTAC case C3L-07034 — Pancreas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/75893e8d-5e50-4c19-82c2-2f2c208c216b

Demographics
Sex at birth: male; Race: white; Year of birth: 1944.

Other clinical attributes
- Weight: 79.7 kg; Height: 176 cm; BMI: 25.73.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (1 sample)
- Sample C3L-07034-01: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 50 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
